Gene-level copy-number profile of tumor specimen TCGA-24-1616-01A from TCGA case TCGA-24-1616, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.9 years (20,785 days).
Specimen TCGA-24-1616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9cfb8540-1bc2-479f-b408-d662cdb6b990.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1616-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d3f1d4da-d0c4-4bae-97bc-d13f1c44f8c2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 797; copy number 2: 14,058; copy number 3: 20,259; copy number 4: 17,374; copy number 5: 3,166; copy number 6: 1,945; copy number 7: 487; copy number 8: 339; copy number 9: 1,040; copy number 10: 27; copy number 11: 29; copy number 12: 57; copy number 14: 20; copy number 16: 10; copy number 23: 81; copy number 25: 87; copy number 33: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1616-01A-01D-0497-01): tumor purity 0.8, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,213 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,869,808–35,930,532, 1 gene, copy number 33 (within-gene range 2–33): AGO1.
- chr1:35,908,980–45,306,209, 310 genes, copy number 9–33 (within-gene range 4–33) (broad region; genes not listed).
- chr1:83,575,776–83,861,023, 2 genes, copy number 8 (within-gene range 4–8): LINC01725, AL035706.1.
- chr1:85,152,487–85,600,734, 14 genes, copy number 9: AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1.
- chr1:92,508,696–92,792,404, 1 gene, copy number 9 (within-gene range 4–9): EVI5.
- chr1:92,647,048–93,554,661, 29 genes, copy number 9: HMGB3P9, RNU4-59P, AC104332.1, H3P3, CCNJP2, RPL5, DIPK1A, SNORD21, SNORA66, AL162740.1, AL449283.1, RNU6-970P, RN7SL692P, AC093577.1, RNU6-210P, RN7SKP123, Y_RNA, MTF2, TMED5, CCDC18, AC126124.2, AC126124.1, CCDC18-AS1, AL139421.1, DR1, AL137159.1, Y_RNA, FNBP1L, RNA5SP53.
- chr1:113,576,757–113,977,869, 12 genes, copy number 8: MTND5P20, PHTF1, AL133517.1, RSBN1, AL137856.1, PTPN22, AP4B1-AS1, BCL2L15, AP4B1, DCLRE1B, HIPK1-AS1, HIPK1.
- chr1:114,001,433–114,002,235, 1 gene, copy number 8: AL591742.1.
- chr3:86,816,740–87,276,584, 7 genes, copy number 8: AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1.
- chr4:64,275,257–67,701,155, 39 genes, copy number 7–9: TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, AC104689.2, LINC02232, AC107058.1, EFL1P2, AC096754.1, LINC02835, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3, RNU6-699P, AC104806.2, RNU1-63P, RNA5SP527, AC104806.1, CENPC, STAP1, AC096720.2, UBA6, AC096720.1.
- chr4:67,716,375–67,773,854, 6 genes, copy number 7: ST3GAL1P1, AC079880.1, AC079880.2, GNRHR, SNORA62, TMPRSS11CP.
- chr4:68,226,653–76,783,253, 191 genes, copy number 9–23 (within-gene range 2–23) (broad region; genes not listed).
- chr5:58,198–24,850,971, 401 genes, copy number 7–8 (broad region; genes not listed).
- chr5:26,382,519–45,895,970, 294 genes, copy number 8–9 (broad region; genes not listed).
- chr7:127,058,088–150,374,044, 592 genes, copy number 7–16 (broad region; genes not listed).
- chr19:9,383,581–14,612,035, 311 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr19:14,621,634–14,628,801, 2 genes, copy number 12: ITGB1P1, AC022149.1.

Autosomal genes at a single copy (total copy number 1): 797. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
